Gene-level copy-number profile of tumor specimen AP-QAHT-PM from APOLLO case AP-QAHT, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Invasive mucinous adenocarcinoma; Tissue or organ of origin: Lung, NOS; Tumor grade: G3.
Specimen AP-QAHT-PM: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 719ba21a-9690-4e11-a611-3907bd7f956c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-QAHT-5V (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/a3d556a0-d25a-4193-af7e-d0c462920c24

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 252; copy number 1: 19,116; copy number 2: 38,301; copy number 3: 1,121; copy number 4: 11; copy number 5: 100.

Homozygous deletions (total copy number 0; autosomes only): 252 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:9,922,113–10,181,239, 12 genes: LZIC, AL357140.2, NMNAT1, RN7SKP269, TMEM274P, MIR5697, AL603962.1, RBP7, UBE4B, AL590639.1, PGAM1P11, RNU6-828P.
- chr1:10,227,718–10,227,803, 1 gene (within-gene range 0–1): AL358013.1.
- chr2:89,319,625–89,600,680, 3 genes: IGKV1-39, IGKV2-40, 5S_rRNA.
- chr3:47,016,429–49,930,173, 131 genes (within-gene range 0–1) (broad region; genes not listed).
- chr3:90,261,414–90,261,708, 1 gene: HSPE1P19.
- chr5:45,890,216–45,895,970, 1 gene: AC122694.1.
- chr18:11,851,413–12,057,822, 13 genes (within-gene range 0–3): CHMP1B, CHMP1B-AS1, AP005137.2, MPPE1, AP001269.4, AP001269.2, AP001269.3, IMPA2, AP001269.1, AP001542.3, AP001542.1, AP001542.2, AP002414.1.
- chr18:12,446,512–15,330,282, 90 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 100 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:22,086,407–22,552,156, 97 genes, copy number 5 (broad region; genes not listed).
- chr21:46,635,595–46,691,226, 3 genes, copy number 5: PRMT2, DSTNP1, RPL23AP4.

Autosomal genes at a single copy (total copy number 1): 16,260. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
